Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UE, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UE-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
High grade leiomyosarcoma.

Specimens Submitted:

- 1: SOFT TISSUE, INTERCOSTAL; BIOPSY
- 2: SOFT TISSUE, RIGHT PARASPINAL; RADICAL RESECTION

DIAGNOSIS:

- 1. SOFT TISSUE, INTERCOSTAL; BIOPSY:
- HIGH GRADE LEIOMYOSARCOMA.
- 2. SOFT TISSUE, RIGHT PARASPINAL; RADICAL RESECTION:
- HIGH GRADE LEIOMYOSARCOMA.
- TUMOR MEASURES 6.6 CM GREATEST DIMENSION, INVOLVES SKELETAL MUSCLE AND FIBROADIPOSE TISSUE, AND SHOWS LESS THAN 5% NECROSIS.
- TUMOR IS 0.1 CM FROM ANTERIOR, 0.4 CM FROM POSTERIOR, AND 0.2 CM FROM SUPERIOR INKED MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1). The specimen is received fresh for frozen section consultation, labeled "intercostal nodule" and consists of single white tan firm nodule measuring 1 x 0.7 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

** Continued on next page **

1CD-03

leiomyosarcoma, NOS
8890/3

Site: soft tissue, trunk
C49.6

52-12

RD

[page 2 of 3]
SURGICAL

Page 2 of 3

2). The specimen is received fresh, labeled "radical resection right paraspinal sarcoma short stitch superior, long stitch lateral" and consists of a fragment of fibroadipose tissue and skeletal muscle measuring 15.4 cm superior inferior, 4.9 cm medial to lateral, and 2.8 cm anterior to posterior. The surface has a 15.4 x 2.3 cm skin ellipse. The specimen is inked: Black -- superior, green -- inferior, red -- lateral, yellow -- anterior, and blue -- posterior. Sections show a 6.6 x 4.4 x 3.9 cm well circumscribed whorled yellow-tan bulging mass located in the skeletal muscle 1 cm from the lateral margin, 0.3 cm from the superior margin, 0.9 cm from the inferior margin, 0.1 cm from the anterior margin, 0.2 cm from the posterior margin, and 9.3 cm from the skin surface. Photographs are taken. TPS is submitted. The specimen is representatively submitted.

Summary of sections:

ST- skin tips

SS-skin

AM-anterior margin

PM-posterior margin

LM-lateral margin

SM-superior margin

IM-inferior margin

T-tumor

SKM-skeletal muscle

AT-adipose tissue

Summary of Sections:

Part 1: SOFT TISSUE, INTERCOSTAL; BIOPSY

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SOFT TISSUE, RIGHT PARASPINAL; RADICAL RESECTION

Block	Sect.	Site	PCs
1		AM	1
2		AT	2
1		IM	1
1		LM	1
1		PM	1
2		SKM	2
1		SM	1
1		SS	1
2		ST	2
5		T	5

** Continued on next page **

[page 3 of 3]
SURGICAL

----- Page 3 of 3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: HIGH GRADE LEIOMYOSARCOMA. (
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file 19b7f187-0f3c-46c4-910b-f2f9ac5217b7 (TCGA-DX-A3UE.CEB90CAD-3C0B-4AF6-9BF2-0B85DE5D4418.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).